Somatic mutation profile of tumor specimen TCGA-EY-A1GP-01A (aliquot TCGA-EY-A1GP-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 54.8 years (20,011 days).
Specimen TCGA-EY-A1GP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 895a17c7-bda4-42a5-99ee-b538b69881b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GP-10A (Blood Derived Normal), aliquot TCGA-EY-A1GP-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8605ba00-a1f5-4a9f-837e-161ade3439ac

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 3, Frame Shift Ins 3, Splice Region 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 24/33 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 23/25 reads (92%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.2879T>G p.I960S (on ENST00000357008 / NM_001363606.2; = p.I973S on NM_001273.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100539412; called by muse, mutect2, varscan2
- DRAXIN | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774730602, COSV53843427; called by muse, mutect2, varscan2
- FAM83E | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs773253521, COSV99320410; called by muse, mutect2, varscan2
- GPR156 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 30/45 reads (67%) | catalogued as rs553212940, COSV59940911; called by muse, mutect2, varscan2
- HGS | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as COSV61269425; called by muse, mutect2, varscan2
- HSPH1 | c.1984C>A p.H662N | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100185220; called by muse, mutect2, varscan2
- INTS1 | c.3264C>T p.D1088= | Splice Region (SNP) | VAF 22/60 reads (37%) | catalogued as rs377762908; called by muse, mutect2, varscan2
- KMT2D | c.10383G>T p.R3461S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as rs915492855, COSV99986355; called by muse, mutect2, varscan2
- LNX1 | c.946G>C p.G316R (on ENST00000263925 / NM_001126328.3; = p.G220R on NM_032622.2) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99820700; called by muse, mutect2, varscan2
- MOGAT3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV56175858; called by muse, mutect2, varscan2
- MRPS31 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100062547; called by muse, mutect2, varscan2
- MYO5C | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 38/49 reads (78%) | catalogued as rs760127579, COSV55904314; called by muse, mutect2, varscan2
- NTNG2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.04); catalogued as rs753771242, COSV62366022, COSV62366228; called by muse, mutect2
- OR13C9 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1410381747, COSV99403578; called by muse, mutect2, varscan2
- PCBP3 | c.1116A>T p.*372Yext*35 | Nonstop Mutation (SNP) | VAF 28/33 reads (85%) | catalogued as COSV101234384; called by muse, mutect2, varscan2
- PRB4 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.096); catalogued as COSV54400570, COSV99686874; called by muse, mutect2, varscan2
- SLC12A2 | c.3414G>T p.E1138D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs1481329326; called by muse, mutect2
- TBC1D16 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757778319, COSV100188446; called by muse, mutect2, varscan2
- USP6 | c.4020G>A p.W1340* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as COSV100005089; called by muse, mutect2, varscan2
- VSNL1 | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99723413; called by muse, mutect2, varscan2
- ZDHHC5 | c.1943A>T p.E648V | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as COSV99762667; called by muse, mutect2, varscan2
- RUNX2 | c.563_570dup p.S191Wfs*12 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | called by mutect2, varscan2
- SAP30BP | c.21dup p.L8Sfs*16 | Frame Shift Ins (INS) | VAF 39/115 reads (34%) | called by mutect2, pindel, varscan2
- TRPS1 | c.2816_2820dup p.G941Tfs*42 (on ENST00000220888 / NM_001330599.2; = p.G954Tfs*42 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- CACNA1D | c.2445G>A p.K815= (on ENST00000350061 / NM_001128840.3; = p.K835= on NM_000720.4) | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as COSV99860363; called by muse, mutect2, varscan2
- ERVFRD-1 | c.120C>G p.S40= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100977436; called by muse, mutect2, varscan2
- F11 | c.1626C>T p.N542= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs750622854, COSV53001256; called by muse, mutect2
- MRPS25 | c.499C>T p.L167= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99507869; called by muse, mutect2, varscan2
- PTCHD4 | c.2424G>A p.T808= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs1399343562, COSV59781073; called by muse, mutect2, varscan2
- URB2 | c.4116C>T p.N1372= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as rs755941015, COSV99272042; called by muse, mutect2, varscan2
- KRT18P55 | n.1039C>G | RNA (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
